Somatic mutation profile of tumor specimen TARGET-30-PASTXR-01A (aliquot TARGET-30-PASTXR-01A-01D) from TARGET case TARGET-30-PASTXR, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 3.0 years (1,100 days).
Specimen TARGET-30-PASTXR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79ab7a30-6fad-420f-b9e1-f2e163efcb65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASTXR-10A (Blood Derived Normal), aliquot TARGET-30-PASTXR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25e991b7-95c3-4ca4-9a1e-424496cbf684

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 5, Silent 5, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY3 | c.2338A>T p.M780L | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as COSV53168255; called by muse, mutect2, varscan2
- DNAH3 | c.6331C>A p.Q2111K | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54526182; called by muse, mutect2, varscan2
- HIVEP1 | c.6755C>T p.A2252V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs543641301, COSV65102178; called by muse, mutect2, varscan2
- PSG8 | c.546G>T p.M182I | Missense Mutation (SNP) | VAF 139/302 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs756703739, COSV60611083, COSV60612403; called by muse, mutect2, varscan2
- RP1 | c.2456T>A p.L819* | Nonsense Mutation (SNP) | VAF 20/42 reads (48%) | catalogued as COSV55118298; called by muse, mutect2, varscan2
- SHANK2 | c.3505G>A p.A1169T | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs537912689, COSV53598323; called by muse, mutect2, varscan2
- H2AC11 | c.285_287del p.N95del | In Frame Del (DEL) | VAF 28/117 reads (24%) | called by pindel, varscan2
- C3 | c.1350C>A p.G450= | Silent (SNP) | VAF 40/80 reads (50%) | catalogued as COSV55574093; called by muse, mutect2, varscan2
- CTNNA3 | c.2310A>G p.E770= | Silent (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2, varscan2
- ENPP1 | c.468G>A p.E156= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV62932802; called by muse, mutect2, varscan2
- PCDHB5 | c.1272C>T p.D424= | Silent (SNP) | VAF 56/108 reads (52%) | catalogued as COSV50654085, COSV50673173; called by muse, mutect2, varscan2
- URGCP | c.843C>T p.A281= (on ENST00000453200 / NM_001077663.3; = p.A272= on NM_017920.4) | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as rs748072445, COSV56248332; called by muse, mutect2, varscan2
